Somatic mutation profile of tumor specimen TCGA-13-0923-01A (aliquot TCGA-13-0923-01A-01W-0420-08) from TCGA case TCGA-13-0923, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 74.1 years (27,081 days).
Specimen TCGA-13-0923-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16aa11a8-bf0f-494f-901b-28619b80d1f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0923-10A (Blood Derived Normal), aliquot TCGA-13-0923-10A-01D-0399-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47a7f244-2636-47e2-b08c-aec3cbd1964f

The open-access MAF lists 207 somatic variants for this specimen: 171 protein-altering or splice-affecting, 29 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 137, Silent 29, Nonsense Mutation 11, Frame Shift Del 7, Splice Site 6, Intron 5, Frame Shift Ins 5, In Frame Del 4, RNA 1, 3'Flank 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.559+2T>G p.X187_splice | Splice Site (SNP) | VAF 242/314 reads (77%) | hotspot (GDC flag); catalogued as CS114004, COSV52709511, COSV52900265, COSV53486980, COSV99478821; called by muse, mutect2, varscan2
- ACAD9 | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs764896398, COSV58310698; called by muse, mutect2, varscan2
- ADAM23 | c.1732G>A p.G578S | Missense Mutation (SNP) | VAF 78/448 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as COSV52233726; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4429G>A p.V1477M | Missense Mutation (SNP) | VAF 24/432 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs763688024, COSV101000509; called by muse, mutect2
- ADAP1 | c.991G>C p.D331H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.946); catalogued as COSV99763112; called by muse, varscan2
- ADGRV1 | c.7925A>T p.E2642V | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.613); catalogued as COSV67995173, COSV67997063; called by muse, mutect2, varscan2
- AGO4 | c.748A>G p.K250E | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV64619097; called by muse, mutect2, varscan2
- ALDH3A2 | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51569384; called by muse, mutect2, varscan2
- APAF1 | c.437A>T p.E146V (on ENST00000551964 / NM_181861.2; = p.E135V on NM_001160.3) | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.497); catalogued as COSV54491517; called by muse, mutect2, varscan2
- API5 | c.243A>C p.Q81H | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as COSV66635493; called by muse, mutect2, varscan2
- APOA4 | c.454C>G p.Q152E | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as COSV100759400, COSV63360889; called by muse, mutect2, varscan2
- ARHGEF40 | c.4459dup p.H1487Pfs*28 | Frame Shift Ins (INS) | VAF 13/89 reads (15%) | catalogued as rs758492903; called by mutect2, varscan2
- BCAS2 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as rs1347500523; called by muse, mutect2
- CAVIN2 | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 82/487 reads (17%) | catalogued as COSV58424460; called by muse, mutect2, varscan2
- CCT3 | c.733C>G p.L245V | Missense Mutation (SNP) | VAF 61/227 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1026650954, COSV55292189; called by muse, mutect2, varscan2
- CD163L1 | c.2291C>A p.A764D | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.703); catalogued as COSV58019967, COSV58026466; called by muse, mutect2, varscan2
- CD1C | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 163/996 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV63806840, COSV63807957; called by muse, mutect2, varscan2
- CD244 | c.820G>A p.V274I (on ENST00000368033 / NM_001166663.2; = p.V269I on NM_016382.4) | Missense Mutation (SNP) | VAF 61/494 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.152); catalogued as rs1427127079, COSV59242381; called by muse, mutect2, varscan2
- CD84 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 81/709 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs907105760, COSV60866855; called by muse, mutect2, varscan2
- CDH23 | c.6931C>T p.P2311S | Missense Mutation (SNP) | VAF 70/553 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.87); catalogued as rs1295012866, COSV56495375; called by mutect2, varscan2
- CDKN2D | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.129); catalogued as rs1335255273, COSV100224767, COSV100224846; called by muse, mutect2, varscan2
- CDKN2D | c.448G>C p.G150R | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.928); catalogued as COSV100224851; called by muse, mutect2, varscan2
- CEBPE | c.800T>C p.I267T | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV52830930; called by muse, mutect2, varscan2
- CHD7 | c.2167G>C p.E723Q | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV71110901; called by muse, mutect2
- CHPF2 | c.159G>C p.Q53H | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.211); catalogued as COSV50404870; called by muse, mutect2, varscan2
- CLNK | c.134A>G p.K45R | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV57023960; called by muse, mutect2, varscan2
- CNOT3 | c.1073G>T p.S358I | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV55369459; called by muse, mutect2, varscan2
- CNOT3 | c.2052G>C p.Q684H | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55369467; called by muse, mutect2, varscan2
- CNTNAP2 | c.2209A>T p.T737S | Missense Mutation (SNP) | VAF 38/364 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV62271881; called by muse, mutect2, varscan2
- COL11A2 | c.3109C>A p.P1037T (on ENST00000341947 / NM_080680.3; = p.P930T on NM_080679.2) | Missense Mutation (SNP) | VAF 59/82 reads (72%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs757865032, COSV59502019; called by muse, mutect2, varscan2
- CR2 | c.1927C>G p.R643G | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100889579, COSV65506234; called by muse, mutect2
- CSMD2 | c.3940T>A p.F1314I | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV53974305; called by muse, mutect2, varscan2
- CUX1 | c.3163C>A p.P1055T | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV52919410; called by muse, mutect2, varscan2
- CYP24A1 | c.709A>T p.N237Y | Missense Mutation (SNP) | VAF 55/450 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV53777303; called by muse, mutect2, varscan2
- CYP2C19 | c.971A>G p.Q324R | Missense Mutation (SNP) | VAF 107/274 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as rs1387059835, COSV64909852; called by muse, mutect2, varscan2
- DDX39B | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 136/190 reads (72%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV58215331; called by muse, mutect2, varscan2
- DDX41 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 27/269 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV57902475, COSV57905825; called by muse, mutect2, varscan2
- DEFB118 | c.272C>A p.T91K | Missense Mutation (SNP) | VAF 72/499 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.258); catalogued as COSV53621940; called by muse, mutect2, varscan2
- DESI1 | c.179dup p.G62Rfs*12 | Frame Shift Ins (INS) | VAF 6/60 reads (10%) | catalogued as rs772952216; called by pindel, varscan2
- DIP2B | c.797-1G>C p.X266_splice | Splice Site (SNP) | VAF 7/62 reads (11%) | catalogued as COSV56593928; called by muse, mutect2, varscan2
- DUOX1 | c.3618T>A p.Y1206* | Nonsense Mutation (SNP) | VAF 61/209 reads (29%) | catalogued as COSV58487560; called by muse, mutect2, varscan2
- DYNC1H1 | c.10945C>G p.L3649V | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64144188; called by muse, mutect2, varscan2
- DYSF | c.4744A>G p.I1582V | Missense Mutation (SNP) | VAF 42/261 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV50647452; called by muse, mutect2, varscan2
- EFNB2 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 139/207 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.312); catalogued as COSV55367761, COSV99809013; called by muse, mutect2, varscan2
- EFTUD2 | c.1808T>A p.M603K | Missense Mutation (SNP) | VAF 106/465 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV68185274; called by muse, mutect2, varscan2
- EIF5B | c.2698C>A p.Q900K | Missense Mutation (SNP) | VAF 122/285 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV56812927, COSV56817268; called by muse, mutect2, varscan2
- EMP2 | c.10C>G p.L4V | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.047); catalogued as rs747583813; called by muse, mutect2
- EPB41L3 | c.707A>G p.E236G | Missense Mutation (SNP) | VAF 71/254 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59468445; called by muse, mutect2, varscan2
- EPHA5 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1439062174, COSV56640804; called by muse, mutect2
- EPHA7 | c.1446G>T p.E482D | Missense Mutation (SNP) | VAF 94/260 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV65193862; called by muse, mutect2, varscan2
- EYA3 | c.1438C>G p.L480V | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65818056; called by muse, mutect2, varscan2
- FANCI | c.3056G>A p.R1019Q (on ENST00000310775 / NM_001376911.1; = p.R959Q on NM_018193.3) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs772401747, COSV55536301; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FARSB | c.1507A>C p.N503H | Missense Mutation (SNP) | VAF 61/334 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV56053283; called by muse, mutect2, varscan2
- FUBP3 | c.1250C>A p.A417D | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60517241; called by muse, mutect2, varscan2
- GOLGB1 | c.7690G>T p.E2564* | Nonsense Mutation (SNP) | VAF 22/114 reads (19%) | catalogued as COSV61472452; called by muse, mutect2, varscan2
- GRPR | c.729T>A p.N243K | Missense Mutation (SNP) | VAF 79/237 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV66670425; called by muse, mutect2, varscan2
- GSS | c.412C>G p.P138A | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV53814858; called by muse, mutect2, varscan2
- HERC5 | c.2378T>G p.F793C | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52046171; called by muse, mutect2, varscan2
- HERPUD2 | c.764A>G p.E255G | Missense Mutation (SNP) | VAF 40/251 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as COSV60947899; called by muse, mutect2, varscan2
- HOXB4 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs532963118, COSV60179110; called by muse, mutect2, varscan2
- HOXC11 | c.691dup p.R231Pfs*148 | Frame Shift Ins (INS) | VAF 20/208 reads (10%) | catalogued as rs772060784; called by mutect2, pindel
- HTR2C | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV52227359; called by muse, mutect2, varscan2
- IGFBPL1 | c.583C>A p.P195T | Missense Mutation (SNP) | VAF 9/205 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100890749, COSV66618092; called by muse, mutect2
- IL4I1 | c.304C>G p.R102G | Missense Mutation (SNP) | VAF 71/156 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62012558; called by muse, mutect2, varscan2
- ITGB7 | c.553G>A p.V185I | Missense Mutation (SNP) | VAF 108/805 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.097); catalogued as COSV57240847; called by muse, mutect2, varscan2
- ITK | c.1045G>T p.A349S | Missense Mutation (SNP) | VAF 143/469 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV101439819, COSV70065581; called by muse, mutect2, varscan2
- KITLG | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57200952; called by muse, mutect2, varscan2
- LAMA4 | c.1012C>T p.Q338* (on ENST00000230538 / NM_001105206.3; = p.Q331* on NM_002290.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 104/289 reads (36%) | catalogued as COSV57906513; called by muse, mutect2, varscan2
- LNPEP | c.1544G>T p.R515L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.055); catalogued as COSV51476278, COSV51482229; called by muse, mutect2, varscan2
- LPIN1 | c.1880C>A p.T627N | Missense Mutation (SNP) | VAF 73/343 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV56772228; called by muse, mutect2, varscan2
- LPO | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.821); catalogued as COSV51861354; called by muse, mutect2, varscan2
- LZTS1 | c.1013T>A p.L338H | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56118842; called by muse, mutect2, varscan2
- MARS1 | c.941A>G p.Y314C | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56259438; called by muse, mutect2, varscan2
- MCHR2 | c.941A>G p.Q314R | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369501589, COSV56010086; called by muse, mutect2, varscan2
- MED13L | c.4811C>T p.S1604F | Missense Mutation (SNP) | VAF 75/231 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.372); catalogued as rs138117728, COSV56132808; called by muse, mutect2, varscan2
- MED17 | c.755A>G p.E252G | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV52603682; called by muse, mutect2, varscan2
- MOGAT3 | c.42A>C p.K14N | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs1418337008, COSV56177658; called by muse, mutect2, varscan2
- MPDZ | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 84/490 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV59956466; called by muse, mutect2, varscan2
- MPZ | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 69/452 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV60669544; called by muse, mutect2, varscan2
- MRC1 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 185/218 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100509749, COSV58890064; called by muse, mutect2, varscan2
- NEB | c.18559G>C p.E6187Q | Missense Mutation (SNP) | VAF 111/353 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV51468033; called by muse, mutect2, varscan2
- NOD2 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs760069458, COSV56051365; called by muse, mutect2
- NRK | c.505C>T p.H169Y | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99688337; called by muse, mutect2
- OBSCN | c.2548G>T p.G850W | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52843204; called by muse, mutect2, varscan2
- PALMD | c.598G>C p.D200H | Missense Mutation (SNP) | VAF 175/256 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV54167809; called by muse, mutect2, varscan2
- PARD3B | c.3426C>G p.H1142Q (on ENST00000406610 / NM_001302769.2; = p.H1073Q on NM_057177.7) | Missense Mutation (SNP) | VAF 78/427 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.033); catalogued as COSV62534723; called by muse, mutect2, varscan2
- PCNX2 | c.2417G>A p.R806Q | Missense Mutation (SNP) | VAF 117/186 reads (63%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.961); catalogued as rs369777297; called by muse, mutect2, varscan2
- PDIA4 | c.319A>G p.I107V | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV53727378; called by muse, mutect2, varscan2
- PELI1 | c.934G>A p.G312S | Missense Mutation (SNP) | VAF 14/477 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62730937; called by muse, mutect2
- PFKFB2 | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 98/403 reads (24%) | PolyPhen possibly damaging (0.877); catalogued as COSV65550154; called by muse, mutect2, varscan2
- PIKFYVE | c.5950C>T p.R1984* | Nonsense Mutation (SNP) | VAF 53/261 reads (20%) | catalogued as rs749786842, COSV52240981; called by muse, mutect2, varscan2
- PKD1L1 | c.7511C>A p.S2504* | Nonsense Mutation (SNP) | VAF 26/43 reads (60%) | catalogued as COSV51843457, COSV51845605; called by muse, mutect2, varscan2
- PLAU | c.647C>G p.P216R | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65642246; called by muse, mutect2, varscan2
- PLSCR1 | c.901G>C p.D301H | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61014242; called by muse, mutect2, varscan2
- PSEN2 | c.745G>T p.E249* | Nonsense Mutation (SNP) | VAF 16/270 reads (6%) | catalogued as COSV100423157; called by muse, mutect2
- PSPC1 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.964); catalogued as rs780711402, COSV58888011; called by mutect2, varscan2
- RBBP8 | c.2087G>A p.S696N | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as COSV59096781; called by muse, varscan2
- RHOC | c.177C>A p.D59E | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV53519603; called by muse, mutect2, varscan2
- RHPN2 | c.1643C>T p.S548L | Missense Mutation (SNP) | VAF 53/228 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs370334049, COSV54279659, COSV54286025; called by muse, mutect2, varscan2
- RMND5B | c.598C>G p.H200D | Missense Mutation (SNP) | VAF 77/345 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.281); catalogued as COSV57746720; called by muse, mutect2, varscan2
- RYR2 | c.7012G>C p.E2338Q | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs760051372, COSV63721043; called by muse, mutect2, varscan2
- SEMA3E | c.214G>C p.V72L | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.033); catalogued as rs371960755, COSV57111552; called by muse, mutect2, varscan2
- SH2D3C | c.1094G>T p.G365V (on ENST00000314830 / NM_170600.3; = p.G208V on NM_005489.4) | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.633); catalogued as COSV59130995; called by muse, mutect2, varscan2
- SLC16A2 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs762142912, COSV52083872; called by muse, mutect2, varscan2
- SLC16A4 | c.920C>G p.S307C | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV63917580; called by muse, mutect2, varscan2
- SLC17A4 | c.1165A>G p.R389G | Missense Mutation (SNP) | VAF 46/678 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV64956792; called by muse, mutect2
- SLC5A6 | c.1181G>C p.R394P | Missense Mutation (SNP) | VAF 46/337 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.763); catalogued as COSV60158707, COSV60161839, COSV60162254; called by muse, mutect2, varscan2
- SLK | c.2734G>T p.E912* | Nonsense Mutation (SNP) | VAF 49/108 reads (45%) | catalogued as COSV59823694, COSV59829757; called by muse, mutect2, varscan2
- SP4 | c.1164T>A p.D388E | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV56027184; called by muse, mutect2, varscan2
- SPOCD1 | c.1327G>C p.D443H | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV57100907; called by muse, mutect2, varscan2
- ST14 | c.760T>G p.S254A | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.05); catalogued as COSV53837856; called by muse, mutect2
- ST6GAL1 | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 17/229 reads (7%) | PolyPhen possibly damaging (0.778); catalogued as rs763859098, COSV51477081; called by muse, mutect2
- TAF4 | c.1375C>G p.R459G | Missense Mutation (SNP) | VAF 70/338 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV53339142, COSV53344280; called by muse, mutect2, varscan2
- TBX18 | c.1184G>T p.C395F | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1394757608, COSV63736090, COSV63738623; called by muse, mutect2, varscan2
- TENM2 | c.5252C>A p.S1751Y (on ENST00000518659 / NM_001122679.2; = p.S1512Y on NM_001080428.3) | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69144480; called by muse, mutect2, varscan2
- TK2 | c.628T>C p.*210Qext*18 (on ENST00000299697; = p.*266Qext*18 on NM_004614.5 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 125/243 reads (51%) | catalogued as rs369778804; called by muse, mutect2, varscan2
- TNNT1 | c.586G>C p.D196H | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV52573700, COSV52574078; called by muse, mutect2, varscan2
- TOP2B | c.2585A>G p.Y862C (on ENST00000264331 / NM_001330700.2; = p.Y857C on NM_001068.3) | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51978479; called by muse, mutect2, varscan2
- TRIM29 | c.1162T>A p.S388T | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV59282261, COSV59282461; called by muse, mutect2, varscan2
- TRIP11 | c.1616A>C p.E539A | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.671); catalogued as COSV50914076, COSV50961165, COSV50974032; called by muse, mutect2, varscan2
- TTLL9 | c.470G>C p.R157P | Missense Mutation (SNP) | VAF 51/311 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV60597305; called by muse, mutect2, varscan2
- TTN | c.15320C>T p.A5107V (on ENST00000591111; = p.A4180V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/542 reads (6%) | PolyPhen benign (0.104); catalogued as rs1466084495, COSV100619494; called by muse, mutect2
- USH2A | c.1195A>T p.I399F | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56453378; called by muse, mutect2, varscan2
- USP6 | c.410C>A p.S137* | Nonsense Mutation (SNP) | VAF 34/145 reads (23%) | catalogued as COSV100004383; called by muse, mutect2, varscan2
- VWF | c.6764C>G p.T2255S | Missense Mutation (SNP) | VAF 39/262 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as COSV54637814; called by muse, mutect2, varscan2
- WDR6 | c.2421dup p.R808Afs*3 | Frame Shift Ins (INS) | VAF 10/72 reads (14%) | catalogued as rs750038548; called by mutect2, varscan2
- ZBTB20 | c.1033G>C p.V345L (on ENST00000474710 / NM_001164342.2; = p.V272L on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/205 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as COSV61874246; called by muse, mutect2, varscan2
- ZNF112 | c.366C>A p.F122L (on ENST00000337401 / NM_001083335.2; = p.F116L on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV61619690; called by muse, mutect2, varscan2
- ZNF222 | c.306G>T p.Q102H | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV51828857; called by muse, mutect2, varscan2
- ZNF311 | c.506A>G p.N169S | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1410755817; called by muse, mutect2
- ZNF385D | c.1055G>T p.S352I | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs1239015783, COSV55779469, COSV99029369; called by muse, mutect2, varscan2
- ZNF823 | c.1580A>G p.Y527C | Missense Mutation (SNP) | VAF 66/197 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs746276489, COSV57876999; called by muse, mutect2, varscan2
- ZP4 | c.610A>T p.T204S | Missense Mutation (SNP) | VAF 17/348 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as COSV63913299; called by muse, mutect2
- ACACA | c.6591_6616del p.R2198Gfs*19 | Frame Shift Del (DEL) | VAF 28/110 reads (25%) | called by mutect2, pindel, varscan2
- ADAMTS9 | c.1665_1691del p.Q556_T564del | In Frame Del (DEL) | VAF 78/538 reads (14%) | called by mutect2, pindel
- AGAP1 | c.386dup p.E130Gfs*20 | Frame Shift Ins (INS) | VAF 4/45 reads (9%) | called by pindel, varscan2
- ATG16L1 | c.1576T>A p.F526I (on ENST00000392017 / NM_030803.7; = p.F507I on NM_017974.4) | Missense Mutation (SNP) | VAF 20/382 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2
- BTLA | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 39/140 reads (28%) | called by muse, mutect2, varscan2
- C1orf56 | c.365G>A p.R122K | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT tolerated (0.95); PolyPhen benign (0.009); called by muse, mutect2
- C9orf131 | c.2408C>A p.P803H | Missense Mutation (SNP) | VAF 21/736 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- CHST14 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 23/248 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.348); called by muse, mutect2
- DHRSX | c.805A>T p.T269S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- GSS | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by mutect2, varscan2
- HMCN1 | c.15194_15197del p.E5065Vfs*6 | Frame Shift Del (DEL) | VAF 18/112 reads (16%) | called by mutect2, pindel, varscan2
- ITGAE | c.115A>T p.S39C | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- KCNH2 | c.1946-20_1948del p.X649_splice | Splice Site (DEL) | VAF 38/112 reads (34%) | called by mutect2, pindel, varscan2
- KCNH5 | c.928_942+9del p.X310_splice | Splice Site (DEL) | VAF 24/132 reads (18%) | called by mutect2, pindel
- KIF23 | c.1483C>A p.P495T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- KIF24 | c.1527C>G p.D509E | Missense Mutation (SNP) | VAF 27/681 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KMT2D | c.3067_3083del p.Q1023Sfs*39 | Frame Shift Del (DEL) | VAF 29/296 reads (10%) | called by mutect2, pindel
- LHX4 | c.1076C>G p.P359R | Missense Mutation (SNP) | VAF 274/1076 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MBOAT7 | c.1311_1337del p.A439_L447del | In Frame Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, pindel
- MTCL1 | c.3118_3132del p.F1040_L1044del (on ENST00000306329 / NM_001378206.1; = p.F721_L725del on NM_015210.4) | In Frame Del (DEL) | VAF 22/134 reads (16%) | called by mutect2, pindel
- NBEA | c.4141_4157del p.N1381Ffs*28 | Frame Shift Del (DEL) | VAF 12/27 reads (44%) | called by mutect2, pindel
- NDUFS2 | c.1084_1097del p.K362* | Frame Shift Del (DEL) | VAF 76/751 reads (10%) | called by mutect2, pindel
- OR13C2 | c.422A>G p.Y141C | Missense Mutation (SNP) | VAF 26/508 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.026); called by muse, mutect2
- OR51T1 | c.314_316delinsAATGGCTTTCTAA p.F105* | Nonsense Mutation (INS) | VAF 61/312 reads (20%) | called by pindel, varscan2*
- PABPC1 | c.1059G>T p.M353I | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, varscan2
- PFKM | c.1197_1210del p.S400Cfs*34 | Frame Shift Del (DEL) | VAF 80/702 reads (11%) | called by mutect2, pindel
- PHKA2 | c.349_368del p.N117Gfs*38 | Frame Shift Del (DEL) | VAF 74/256 reads (29%) | called by mutect2, pindel, varscan2
- PRDM10 | c.3176-14_3194del p.X1059_splice | Splice Site (DEL) | VAF 26/65 reads (40%) | called by mutect2, pindel
- RP1L1 | c.1110G>T p.E370D | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.202); called by muse, mutect2
- RPTN | c.2114C>G p.A705G | Missense Mutation (SNP) | VAF 140/1067 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- SLC10A6 | c.851T>C p.V284A | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2
- SLC45A1 | c.1670C>A p.P557H | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPATA31A3 | c.1882G>A p.D628N | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- TMEM87A | c.863_868+26del p.X288_splice | Splice Site (DEL) | VAF 8/39 reads (21%) | called by mutect2, pindel
- TRIM27 | c.1016_1042del p.R339_L347del | In Frame Del (DEL) | VAF 56/622 reads (9%) | called by mutect2, pindel
- ZNF24 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 24/702 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2
- ZNF646 | c.1478A>C p.Q493P | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.362); called by muse, varscan2
- ZNF646 | c.1479G>C p.Q493H | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); called by muse, varscan2
- ADNP | c.114T>C p.F38= | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as rs1205146288, COSV62427141; called by muse, mutect2
- ADNP2 | c.933G>A p.V311= | Silent (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- ANO5 | c.2085T>A p.L695= | Silent (SNP) | VAF 75/242 reads (31%) | catalogued as COSV61091282; called by muse, mutect2, varscan2
- B3GAT3 | c.570C>T p.V190= | Silent (SNP) | VAF 57/213 reads (27%) | catalogued as COSV53884958; called by muse, mutect2, varscan2
- C6orf47 | c.813C>A p.A271= | Silent (SNP) | VAF 10/216 reads (5%) | called by muse, mutect2
- CMKLR1 | c.330C>G p.A110= (on ENST00000312143 / NM_001142344.2; = p.A108= on NM_004072.3) | Silent (SNP) | VAF 146/340 reads (43%) | catalogued as COSV56442806; called by muse, mutect2, varscan2
- DAB1 | c.1011C>T p.G337= (on ENST00000371231; = p.G304= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as rs1482139714, COSV100976322, COSV64691347; called by muse, mutect2, varscan2
- DDX60 | c.1429T>C p.L477= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs1365535166, COSV67099893; called by muse, mutect2, varscan2
- DLG5 | c.4524C>A p.S1508= | Silent (SNP) | VAF 272/471 reads (58%) | catalogued as COSV64947532, COSV64950410; called by muse, mutect2, varscan2
- FCGR2A | c.675G>A p.A225= (on ENST00000271450 / NM_001136219.3; = p.A224= on NM_021642.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 235/1810 reads (13%) | catalogued as rs757723528, COSV54841350; called by muse, mutect2, varscan2
- GEMIN4 | c.855C>T p.H285= | Silent (SNP) | VAF 22/150 reads (15%) | catalogued as rs1257302179, COSV56748031; called by muse, mutect2, varscan2
- GLUD2 | c.879A>G p.L293= | Silent (SNP) | VAF 67/114 reads (59%) | catalogued as COSV60153484; called by muse, mutect2, varscan2
- GRIA3 | c.984A>G p.R328= | Silent (SNP) | VAF 31/53 reads (58%) | catalogued as COSV52084159; called by muse, mutect2, varscan2
- IRAG1 | c.915C>G p.G305= | Silent (SNP) | VAF 8/60 reads (13%) | called by mutect2, varscan2
- LNPK | c.753A>G p.R251= | Silent (SNP) | VAF 27/42 reads (64%) | catalogued as COSV55826867; called by muse, mutect2, varscan2
- LPAR2 | c.918C>T p.F306= | Silent (SNP) | VAF 22/145 reads (15%) | catalogued as COSV101345534; called by muse, mutect2, varscan2
- LRTM2 | c.1005C>T p.Y335= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as rs750674817, COSV54564397; called by muse, mutect2, varscan2
- MUC17 | c.6942T>A p.T2314= | Silent (SNP) | VAF 38/436 reads (9%) | catalogued as COSV60307420; called by muse, mutect2
- NCL | c.630T>A p.A210= | Silent (SNP) | VAF 35/217 reads (16%) | catalogued as COSV59547849; called by muse, mutect2, varscan2
- RASGEF1A | c.1266A>T p.T422= | Silent (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- SLC2A1 | c.279G>C p.R93= | Silent (SNP) | VAF 12/334 reads (4%) | catalogued as COSV100995910; called by muse, mutect2
- SLC45A2 | c.678C>T p.L226= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as rs1387107095, COSV56873321; called by muse, mutect2, varscan2
- SLCO6A1 | c.1452G>A p.G484= | Silent (SNP) | VAF 21/139 reads (15%) | catalogued as COSV65815826; called by muse, mutect2, varscan2
- SPHKAP | c.1716T>C p.G572= | Silent (SNP) | VAF 16/510 reads (3%) | catalogued as COSV100764262; called by muse, mutect2
- TRIP11 | c.1170A>G p.L390= | Silent (SNP) | VAF 70/231 reads (30%) | catalogued as COSV50974168; called by muse, mutect2, varscan2
- ZIC3 | c.1155C>T p.D385= | Silent (SNP) | VAF 112/172 reads (65%) | catalogued as COSV54977680; called by muse, mutect2, varscan2
- ZNF586 | c.240A>G p.G80= | Silent (SNP) | VAF 54/285 reads (19%) | catalogued as COSV66972805; called by muse, mutect2, varscan2
- ZNF80 | c.276C>T p.F92= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs774250881, COSV57359912; called by muse, mutect2, varscan2
- ZNF804B | c.2055C>A p.T685= | Silent (SNP) | VAF 35/140 reads (25%) | catalogued as rs750485373, COSV60862505; called by muse, mutect2, varscan2
- ASH1L | c.7905+18T>A | Intron (SNP) | VAF 106/1017 reads (10%) | catalogued as COSV100853493; called by muse, mutect2, varscan2
- BSDC1 | c.190-30G>T | Intron (SNP) | VAF 33/64 reads (52%) | catalogued as rs747628993, COSV61982331; called by muse, mutect2, varscan2
- DFFB | c.242-141C>G | Intron (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- ELP4 | c.1147-19960G>C | Intron (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1662G>T | RNA (SNP) | VAF 18/60 reads (30%) | catalogued as rs1219773904; called by mutect2, varscan2
- RASAL2 | c.3256-2352G>C | Intron (SNP) | VAF 35/227 reads (15%) | called by muse, mutect2, varscan2
- ST8SIA2 | chr15:92472350 C>T | 3'Flank (SNP) | VAF 30/167 reads (18%) | called by muse, mutect2, varscan2
